Somatic mutation profile of tumor specimen TCGA-B9-5155-01A (aliquot TCGA-B9-5155-01A-01D-1589-08) from TCGA case TCGA-B9-5155, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 71.6 years (26,149 days).
Specimen TCGA-B9-5155-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c01053e5-b346-4759-9ef9-8d8eb4f55e18.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B9-5155-10A (Blood Derived Normal), aliquot TCGA-B9-5155-10A-01D-1589-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/31a29b76-e2ae-4e59-a004-0a83fb1d4043

The open-access MAF lists 107 somatic variants for this specimen: 82 protein-altering or splice-affecting, 23 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 62, Silent 23, Frame Shift Del 8, Nonsense Mutation 5, Frame Shift Ins 3, 5'UTR 1, Splice Site 1, Splice Region 1, Translation Start Site 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACOX2 | c.1025C>T p.T342I | Missense Mutation (SNP) | VAF 45/104 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57147638; called by muse, mutect2, varscan2
- AMD1 | c.468T>C p.C156= | Splice Region (SNP) | VAF 159/314 reads (51%) | catalogued as COSV64386961; called by muse, mutect2, varscan2
- ARSJ | c.1786G>A p.V596I | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as COSV59536688; called by muse, mutect2, varscan2
- ASPRV1 | c.194T>C p.L65P | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.819); catalogued as COSV57227386; called by muse, mutect2, varscan2
- ATAD2B | c.1859C>G p.A620G | Missense Mutation (SNP) | VAF 29/63 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV53195139; called by muse, mutect2, varscan2
- AXDND1 | c.2828A>T p.E943V | Missense Mutation (SNP) | VAF 46/116 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62639672; called by muse, mutect2, varscan2
- BRD3 | c.511G>C p.V171L | Missense Mutation (SNP) | VAF 33/61 reads (54%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV57701371; called by muse, mutect2, varscan2
- BTBD8 | c.953C>G p.S318C | Missense Mutation (SNP) | VAF 63/145 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as COSV61544943, COSV61547580; called by muse, mutect2, varscan2
- CAPRIN1 | c.1910A>G p.D637G | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV58218224; called by muse, mutect2, varscan2
- CCAR1 | c.1266G>A p.M422I | Missense Mutation (SNP) | VAF 79/165 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.095); catalogued as COSV56267212; called by muse, mutect2, varscan2
- CCDC141 | c.3955C>T p.H1319Y | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.382); catalogued as COSV55368858; called by muse, mutect2, varscan2
- CCDC157 | c.1825A>G p.I609V | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.59); PolyPhen benign (0.12); catalogued as COSV53175423; called by muse, mutect2
- CCDC198 | c.717A>C p.K239N | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as COSV53601298; called by muse, mutect2, varscan2
- CCIN | c.100G>A p.V34M | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs930631095, COSV58724028; called by muse, mutect2
- CFAP45 | c.1344G>T p.R448S | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.305); catalogued as COSV63648007; called by muse, mutect2, varscan2
- CFAP94 | c.254T>C p.L85S (on ENST00000320267 / NM_001352064.2; = p.L91S on NM_018272.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/67 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV57229981; called by muse, mutect2, varscan2
- COCH | c.562G>T p.V188L (on ENST00000216361 / NM_001347720.1; = p.V123L on NM_004086.3) | Missense Mutation (SNP) | VAF 70/151 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.065); catalogued as COSV53549709; called by muse, mutect2, varscan2
- CTTNBP2NL | c.1843C>G p.L615V | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.03); catalogued as rs201748043, COSV54743016; called by muse, mutect2, varscan2
- DDIAS | c.547C>A p.Q183K | Missense Mutation (SNP) | VAF 84/228 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.162); catalogued as COSV100231048, COSV61271407, COSV61272041; called by muse, mutect2, varscan2
- DDX17 | c.2179T>C p.S727P | Missense Mutation (SNP) | VAF 38/84 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); catalogued as rs144334639; called by muse, varscan2
- DIP2B | c.4651G>T p.G1551* | Nonsense Mutation (SNP) | VAF 45/81 reads (56%) | catalogued as COSV56578876; called by muse, mutect2, varscan2
- DLX5 | c.496G>C p.E166Q | Missense Mutation (SNP) | VAF 56/273 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs376488297, COSV56031710; called by muse, mutect2, varscan2
- DOCK10 | c.3740A>G p.Q1247R | Missense Mutation (SNP) | VAF 26/54 reads (48%) | SIFT tolerated (0.56); PolyPhen benign (0.022); catalogued as COSV51348000; called by muse, mutect2, varscan2
- DPY19L2 | c.1310C>A p.T437K | Missense Mutation (SNP) | VAF 55/134 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV60541179; called by muse, mutect2, varscan2
- DYNC1I1 | c.1523C>T p.S508L | Missense Mutation (SNP) | VAF 111/171 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61455773; called by muse, mutect2, varscan2
- DYNC2H1 | c.10184C>T p.T3395I | Missense Mutation (SNP) | VAF 35/114 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs778720641, COSV62086184; called by muse, mutect2
- EPS15L1 | c.1655A>G p.E552G | Missense Mutation (SNP) | VAF 52/109 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.606); catalogued as COSV50167211; called by muse, mutect2, varscan2
- ERC1 | c.1292G>A p.S431N | Missense Mutation (SNP) | VAF 50/104 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.163); catalogued as COSV61691555; called by muse, mutect2, varscan2
- FOLH1 | c.1910del p.K637Rfs*23 | Frame Shift Del (DEL) | VAF 38/111 reads (34%) | catalogued as COSV57049554; called by mutect2, pindel, varscan2
- FOXF2 | c.493C>G p.L165V | Missense Mutation (SNP) | VAF 61/144 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.684); catalogued as COSV52525047; called by muse, mutect2, varscan2
- GADL1 | c.1387A>G p.N463D | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs757947294, COSV56974977; called by muse, mutect2, varscan2
- GMPR | c.413T>A p.F138Y | Missense Mutation (SNP) | VAF 89/186 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV52472127; called by muse, mutect2, varscan2
- GRK5 | c.1A>T p.M1? | Translation Start Site (SNP) | VAF 17/29 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV67308776, COSV67310749; called by muse, mutect2, varscan2
- HERC1 | c.9157A>C p.T3053P | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV71245947; called by muse, mutect2, varscan2
- HERC4 | c.2090T>C p.L697P (on ENST00000395198 / NM_022079.3; = p.L689P on NM_015601.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/88 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.594); catalogued as COSV53268477; called by muse, mutect2, varscan2
- HS2ST1 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 97/220 reads (44%) | SIFT tolerated (0.23); PolyPhen benign (0.02); catalogued as COSV63348690; called by muse, mutect2, varscan2
- HSPA8 | c.448T>C p.F150L | Missense Mutation (SNP) | VAF 45/103 reads (44%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.163); catalogued as COSV57082588; called by muse, mutect2, varscan2
- IQCB1 | c.1355A>G p.D452G | Missense Mutation (SNP) | VAF 138/239 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV60435153; called by muse, mutect2, varscan2
- KAT6A | c.3198G>T p.E1066D | Missense Mutation (SNP) | VAF 60/151 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.76); catalogued as COSV55902623; called by muse, mutect2
- KIAA0100 | c.6045C>G p.I2015M | Missense Mutation (SNP) | VAF 90/145 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56380703; called by muse, mutect2, varscan2
- KIAA1217 | c.1481G>C p.G494A | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.987); catalogued as COSV56812354, COSV56812844; called by muse, mutect2, varscan2
- KLF6 | c.665G>T p.R222L | Missense Mutation (SNP) | VAF 17/32 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as COSV51493705; called by muse, mutect2, varscan2
- LIG3 | c.430T>C p.F144L | Missense Mutation (SNP) | VAF 39/58 reads (67%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV52005767; called by muse, mutect2, varscan2
- MRE11 | c.130T>G p.L44V | Missense Mutation (SNP) | VAF 59/154 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV60573863; called by muse, mutect2, varscan2
- NIT1 | c.958G>C p.G320R | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV63501143; called by muse, mutect2, varscan2
- PGAP4 | c.773A>G p.E258G | Missense Mutation (SNP) | VAF 63/139 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66387195; called by muse, mutect2, varscan2
- PIGU | c.1079G>A p.C360Y | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV54160406; called by muse, mutect2, varscan2
- PKHD1 | c.1512+1G>T p.X504_splice | Splice Site (SNP) | VAF 50/125 reads (40%) | catalogued as CS032419, COSV61860555; called by muse, mutect2, varscan2
- POLR3A | c.3125G>A p.G1042D | Missense Mutation (SNP) | VAF 70/192 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64930230; called by muse, mutect2, varscan2
- PPIP5K2 | c.2188A>G p.I730V | Missense Mutation (SNP) | VAF 112/237 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0.1); catalogued as rs781982642, COSV58602496; called by muse, mutect2, varscan2
- PRRC2C | c.7582C>T p.Q2528* (on ENST00000367742; = p.Q2526* on NM_015172.4) | Nonsense Mutation (SNP) | VAF 138/311 reads (44%) | catalogued as COSV58900904; called by muse, mutect2, varscan2
- RAB8B | c.403A>T p.R135* | Nonsense Mutation (SNP) | VAF 39/77 reads (51%) | catalogued as COSV58489039; called by muse, mutect2, varscan2
- SERPINA3 | c.506A>G p.D169G | Missense Mutation (SNP) | VAF 38/74 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV67585245; called by muse, mutect2, varscan2
- SETD2 | c.4502G>C p.C1501S | Missense Mutation (SNP) | VAF 101/179 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV57430129, COSV57441923; called by muse, mutect2, varscan2
- SKIDA1 | c.2569A>G p.I857V | Missense Mutation (SNP) | VAF 25/51 reads (49%) | SIFT tolerated (0.47); PolyPhen benign (0.009); catalogued as rs776042701, COSV71610446; called by muse, mutect2, varscan2
- SLC2A12 | c.620G>T p.G207V | Missense Mutation (SNP) | VAF 9/146 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); catalogued as COSV51597688; called by muse, mutect2
- SLC45A2 | c.527A>G p.K176R | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.115); catalogued as COSV56869672; called by muse, mutect2, varscan2
- SLC5A12 | c.839T>C p.L280S | Missense Mutation (SNP) | VAF 34/54 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV54818954; called by muse, mutect2, varscan2
- SPOPL | c.748G>A p.V250I | Missense Mutation (SNP) | VAF 53/108 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV54511815; called by muse, mutect2, varscan2
- SSH2 | c.2725G>C p.A909P | Missense Mutation (SNP) | VAF 328/569 reads (58%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.276); catalogued as COSV52166586; called by muse, mutect2, varscan2
- STAG3 | c.2600T>C p.L867P | Missense Mutation (SNP) | VAF 228/352 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100426150, COSV57927506; called by muse, mutect2, varscan2
- STK11 | c.532A>T p.K178* | Nonsense Mutation (SNP) | VAF 9/18 reads (50%) | catalogued as COSV58820388; called by muse, mutect2, varscan2
- TBX10 | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56875063; called by muse, mutect2
- TMCO4 | c.1231T>C p.Y411H | Missense Mutation (SNP) | VAF 83/145 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53869123; called by muse, mutect2, varscan2
- USF1 | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV57035604; called by muse, mutect2, varscan2
- USP19 | c.2524T>C p.F842L | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.25); catalogued as COSV60044901; called by muse, mutect2, varscan2
- WDCP | c.223G>T p.V75F | Missense Mutation (SNP) | VAF 27/60 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.076); catalogued as COSV54591485; called by muse, mutect2, varscan2
- WEE2 | c.127A>T p.K43* | Nonsense Mutation (SNP) | VAF 184/313 reads (59%) | catalogued as COSV66878143; called by muse, mutect2, varscan2
- ZNF676 | c.1486T>G p.F496V (on ENST00000650058; = p.F464V on NM_001001411.3) | Missense Mutation (SNP) | VAF 94/232 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as COSV68092168; called by muse, mutect2, varscan2
- ZNF830 | c.740C>G p.P247R | Missense Mutation (SNP) | VAF 50/86 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58487821; called by muse, mutect2, varscan2
- HAS2 | c.961del p.V321Cfs*2 | Frame Shift Del (DEL) | VAF 100/249 reads (40%) | called by mutect2, pindel, varscan2
- LINS1 | c.873_875del p.I291_Q292delinsM | In Frame Del (DEL) | VAF 22/62 reads (35%) | called by mutect2, pindel, varscan2
- MBNL1 | c.923_933delinsC p.G308Afs*14 (on ENST00000282486 / NM_207293.2; = p.G290Afs*14 on NM_021038.5 and 10 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 32/163 reads (20%) | called by pindel, varscan2*
- MFGE8 | c.619_620dup p.L207Ffs*22 | Frame Shift Ins (INS) | VAF 66/174 reads (38%) | called by mutect2, pindel, varscan2
- PAIP1 | c.430del p.Y144Tfs*23 | Frame Shift Del (DEL) | VAF 101/306 reads (33%) | called by mutect2, pindel, varscan2
- PARP4 | c.3884del p.P1295Qfs*53 | Frame Shift Del (DEL) | VAF 43/124 reads (35%) | called by mutect2, pindel, varscan2
- PGBD2 | c.485dup p.N162Kfs*53 | Frame Shift Ins (INS) | VAF 90/243 reads (37%) | called by mutect2, pindel, varscan2
- PKP4 | c.3392dup p.L1131Ffs*8 | Frame Shift Ins (INS) | VAF 69/166 reads (42%) | called by mutect2, pindel, varscan2
- RAB28 | c.111del p.F37Lfs*9 | Frame Shift Del (DEL) | VAF 33/92 reads (36%) | called by mutect2, pindel, varscan2
- SEC16A | c.1844A>T p.K615I | Missense Mutation (SNP) | VAF 10/13 reads (77%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TDRD5 | c.1672_1677delinsA p.V558Ifs*67 | Frame Shift Del (DEL) | VAF 68/240 reads (28%) | called by pindel, varscan2*
- TSHZ2 | c.1033del p.S345Lfs*36 | Frame Shift Del (DEL) | VAF 87/224 reads (39%) | called by mutect2, pindel, varscan2
- ARHGEF10L | c.3561G>A p.L1187= | Silent (SNP) | VAF 13/25 reads (52%) | catalogued as COSV51427647; called by muse, mutect2, varscan2
- BNC1 | c.336G>T p.L112= | Silent (SNP) | VAF 74/141 reads (52%) | catalogued as COSV61756504; called by muse, mutect2, varscan2
- C5 | c.3562T>C p.L1188= | Silent (SNP) | VAF 40/97 reads (41%) | catalogued as rs955581138, COSV56324036; called by muse, mutect2, varscan2
- CAPN9 | c.810A>G p.R270= | Silent (SNP) | VAF 50/117 reads (43%) | catalogued as COSV55230470; called by muse, mutect2, varscan2
- CLDN12 | c.228A>G p.S76= | Silent (SNP) | VAF 83/259 reads (32%) | catalogued as rs1488499672, COSV55306160; called by muse, mutect2, varscan2
- CSTF1 | c.933T>A p.S311= | Silent (SNP) | VAF 53/118 reads (45%) | catalogued as COSV53857834; called by muse, mutect2, varscan2
- DDX1 | c.72C>T p.L24= | Silent (SNP) | VAF 6/100 reads (6%) | catalogued as COSV51837974; called by muse, mutect2
- DDX43 | c.1236G>A p.K412= | Silent (SNP) | VAF 90/178 reads (51%) | catalogued as COSV64812173; called by muse, mutect2, varscan2
- IGHA2 | c.24C>A p.V8= | Silent (SNP) | VAF 25/78 reads (32%) | called by muse, mutect2, varscan2
- IL10RA | c.978A>T p.P326= | Silent (SNP) | VAF 27/75 reads (36%) | catalogued as COSV57139730; called by muse, mutect2, varscan2
- JAG2 | c.783G>A p.E261= | Silent (SNP) | VAF 71/134 reads (53%) | catalogued as COSV59306516; called by muse, mutect2, varscan2
- KCNJ15 | c.531C>T p.T177= | Silent (SNP) | VAF 25/65 reads (38%) | catalogued as rs1234992743, COSV60810180; called by muse, mutect2, varscan2
- LRRC8C | c.1125T>C p.H375= | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as COSV64995222; called by muse, mutect2, varscan2
- PCDHB16 | c.1716C>T p.C572= | Silent (SNP) | VAF 55/66 reads (83%) | catalogued as rs568748617, COSV53357692; called by muse, mutect2, varscan2
- PRRC2A | c.6387G>A p.G2129= | Silent (SNP) | VAF 72/164 reads (44%) | catalogued as COSV52987943; called by muse, varscan2
- PSMC2 | c.369G>T p.V123= | Silent (SNP) | VAF 54/157 reads (34%) | catalogued as COSV53006614; called by muse, mutect2, varscan2
- PTCH1 | c.2487G>T p.V829= | Silent (SNP) | VAF 58/144 reads (40%) | catalogued as COSV59462945; called by muse, mutect2, varscan2
- RBM24 | c.573G>A p.G191= (on ENST00000379052 / NM_001143942.2; = p.G146= on NM_153020.2) | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as COSV59002751; called by muse, mutect2, varscan2
- REM1 | c.288G>A p.L96= | Silent (SNP) | VAF 21/39 reads (54%) | catalogued as rs1235182760, COSV52426780, COSV99147241; called by muse, mutect2, varscan2
- SLC35G3 | c.615G>A p.L205= | Silent (SNP) | VAF 152/218 reads (70%) | catalogued as COSV52010185; called by muse, mutect2, varscan2
- SMCR8 | c.1074T>C p.D358= | Silent (SNP) | VAF 45/145 reads (31%) | catalogued as COSV58174887; called by muse, mutect2, varscan2
- SRP19 | c.243A>G p.R81= | Silent (SNP) | VAF 42/98 reads (43%) | catalogued as rs768937848, COSV51582881; called by muse, mutect2, varscan2
- SYDE2 | c.1026A>G p.V342= | Silent (SNP) | VAF 34/71 reads (48%) | catalogued as COSV52314045; called by muse, mutect2, varscan2
- DPF3 | c.871+3037C>G | Intron (SNP) | VAF 17/59 reads (29%) | catalogued as COSV100818473; called by muse, mutect2, varscan2
- SLC22A13 | c.-2A>G | 5'UTR (SNP) | VAF 53/96 reads (55%) | catalogued as COSV100314511; called by muse, mutect2, varscan2
